Surgical pathology report (de-identified scan), TCGA case TCGA-H4-A2HQ, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Medical College of Georgia, specimen TCGA-H4-A2HQ-01A (Primary Tumor).

[page 1 of 2]
Patient Name:
MRN:
DOB: Sex: Female Black
Account Number:
Visit Date:
Discharge date:
Patient Type:
Location:
Attending Physician:

slide

Final Pathology Diagnosis Report

Accession Number: Senior Pathologist:

Collected Date/Time:

Received Date/Time:

Verified Date/Time:

Final Pathologic Diagnosis

BLADDER TUMOR (BIOPSY):

- **High-grade urothelial carcinoma with extensive muscularis propria invasion.**

slide

NOTE: This case was reviewed by another attending pathologist on

I attest I have personally reviewed the specimen/slides and agree with the above findings.

Electronic Signature
Verified:

1CD-0-3
Carcinoma, urothelial, NOS 8/20/3
Site: bladder, NOS C67.9 W 4/18/11

Resident:

Clinical History

old black female with bladder mass.

Pre/Post-operative Diagnosis

Bladder mass.

Gross Anatomic Description

(Dictated by Dr.

Specimen received in one container.

Specimen: Designated "bladder tumor" is received in formalin labeled with the patient's name, MRN and "bladder tumor". Specimen consists of multiple fragments of red blood clot and pink/brown tissue weighing in total of 26 g and measuring 4.0 x 4.0 x 3.0 cm. A representative portion is given to Tumor Bank.

Printed:

Confidential Information

[page 2 of 2]
Patient Name:
MRN:
DOB: Sex: Female Black
Account Number:
Visit Date:
Discharge date:
Patient Type:
Location:
Attending Physician:

F i n a l P a t h o l o g y D i a g n o s i s R e p o r t

Accession Number: Senior Pathologist:

Collected Date/Time:
Received Date/Time:
Verified Date/Time:

Section code: A1-A10 – entire specimen (excluding blood clot).

Source: NCI Genomic Data Commons file 3a316cf1-0184-43f7-823e-d24ececa97ca (TCGA-H4-A2HQ.87991E38-AE15-4163-BC44-6AEA8105A203.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).